Somatic mutation profile of tumor specimen MP2PRT-PAVDRK-TMP1-A (aliquot MP2PRT-PAVDRK-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVDRK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,004 days).
Specimen MP2PRT-PAVDRK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f06b726f-7fee-44d3-9efd-46e7436bb3a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDRK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDRK-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be8689c3-fdd0-4c2a-8e27-8fa4bb157fe8

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.3874C>T p.R1292* | Nonsense Mutation (SNP) | VAF 208/336 reads (62%) | catalogued as COSV54394009; called by muse, mutect2, varscan2
- FAT2 | c.9742G>A p.A3248T | Missense Mutation (SNP) | VAF 162/567 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs372148628; called by muse, mutect2, varscan2
- KDR | c.3262G>T p.V1088F | Missense Mutation (SNP) | VAF 128/351 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55778069; called by muse, mutect2, varscan2
- NCKAP5 | c.4856C>T p.T1619M | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as rs780758821; called by muse, mutect2, varscan2
- RBMXL3 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 127/185 reads (69%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1307596811; called by muse, mutect2, varscan2
- KCNB2 | c.1019T>G p.L340W | Missense Mutation (SNP) | VAF 155/454 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SOX13 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- COX18 | c.78G>A p.A26= | Silent (SNP) | VAF 191/647 reads (30%) | catalogued as rs570492077; called by muse, varscan2
- DISP3 | c.3045C>T p.F1015= | Silent (SNP) | VAF 160/487 reads (33%) | catalogued as rs959278811, COSV53823083; called by muse, mutect2, varscan2
- LAMA1 | c.3111G>A p.A1037= | Silent (SNP) | VAF 90/292 reads (31%) | catalogued as rs200710797, COSV67533149; called by muse, mutect2, varscan2
- LAYN | c.474G>A p.S158= (on ENST00000375615 / NM_001258390.1; = p.S150= on NM_178834.5) | Silent (SNP) | VAF 127/405 reads (31%) | catalogued as rs74926127; called by muse, mutect2, varscan2
- MASP1 | c.1303+5602C>T | Intron (SNP) | VAF 81/595 reads (14%) | catalogued as rs200393551, COSV56225287; ClinVar: likely benign; called by muse, mutect2, varscan2
